Somatic mutation profile of tumor specimen TCGA-SR-A6N0-01A (aliquot TCGA-SR-A6N0-01A-11D-A35I-08) from TCGA case TCGA-SR-A6N0, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 45.1 years (16,489 days).
Specimen TCGA-SR-A6N0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79353866-6bf9-4a85-bc31-9b4ea74d8988.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SR-A6N0-10A (Blood Derived Normal), aliquot TCGA-SR-A6N0-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b093b732-b25d-42e5-b7ca-59a7ef13f410

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Frame Shift Del 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HNF1B | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 5/80 reads (6%) | catalogued as rs1568670481, CM042491; ClinVar: pathogenic; called by muse, mutect2
- ALG6 | c.802del p.R268Vfs*8 | Frame Shift Del (DEL) | VAF 36/176 reads (20%) | catalogued as COSV54765958; called by mutect2, pindel, varscan2
- P4HA2 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 28/453 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs377044728; called by muse, mutect2
- OR6C76 | c.41G>A p.G14D | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- TRIO | c.4180A>T p.T1394S | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- NOTCH4 | c.1851T>C p.S617= | Silent (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
